Somatic mutation profile of tumor specimen TARGET-10-PATCUK-09A (aliquot TARGET-10-PATCUK-09A-01D) from TARGET case TARGET-10-PATCUK, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 12.0 years (4,397 days).
Specimen TARGET-10-PATCUK-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) fdb39872-4436-4920-98c3-e395522eed9f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PATCUK-14A (Bone Marrow Normal), aliquot TARGET-10-PATCUK-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b42ffa7f-3372-4bf5-b151-e05bc048e32c

The open-access MAF lists 18 somatic variants for this specimen: 12 protein-altering or splice-affecting, 2 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 8, Frame Shift Del 2, Silent 2, Intron 1, 5'UTR 1, In Frame Ins 1, 3'Flank 1, Frame Shift Ins 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FBXW7 | c.1514G>A p.R505H (on ENST00000281708 / NM_001349798.2; = p.R425H on NM_018315.5) | Missense Mutation (SNP) | VAF 12/78 reads (15%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1057519896, COSV55901126, COSV55908371, COSV55911517; ClinVar: likely pathogenic / uncertain significance; called by muse, varscan2
- FBXW7 | c.1436G>A p.R479Q (on ENST00000281708 / NM_001349798.2; = p.R399Q on NM_018315.5) | Missense Mutation (SNP) | VAF 24/77 reads (31%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs866987936, COSV55890822, COSV55894913, COSV55899054; ClinVar: likely pathogenic; called by muse, varscan2
- ANK3 | c.1769C>T p.S590F | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.93); catalogued as rs1319363351, COSV55052742; called by muse, mutect2, varscan2
- CCDC88C | c.1967C>T p.T656I | Missense Mutation (SNP) | VAF 14/72 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV66237029; called by muse, mutect2, varscan2
- CLEC5A | c.416G>T p.R139M | Missense Mutation (SNP) | VAF 29/70 reads (41%) | SIFT tolerated (0.07); PolyPhen benign (0.023); catalogued as rs781867395, COSV69397057; called by muse, mutect2, varscan2
- DNAH1 | c.11556del p.C3853Afs*43 | Frame Shift Del (DEL) | VAF 15/50 reads (30%) | catalogued as COSV56232988; called by mutect2, pindel, varscan2
- GFRA1 | c.677G>A p.R226Q | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.509); catalogued as rs777650834, COSV62603981, COSV62607405; called by muse, mutect2, varscan2
- NOTCH1 | c.5033T>C p.L1678P | Missense Mutation (SNP) | VAF 16/47 reads (34%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV53024869, COSV53029241; called by muse, mutect2, varscan2
- TBX21 | c.1508C>T p.S503F | Missense Mutation (SNP) | VAF 27/63 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV51595679; called by muse, mutect2, varscan2
- BCL11B | c.1347_1348insGCTTCCACTAGA p.H449_T450insASTR (on ENST00000357195 / NM_001282237.2; = p.H378_T379insASTR on NM_022898.3 and 1 other RefSeq transcript) | In Frame Ins (INS) | VAF 4/23 reads (17%) | called by mutect2, pindel*
- USP7 | c.757dup p.S253Ffs*2 | Frame Shift Ins (INS) | VAF 4/34 reads (12%) | called by mutect2, pindel, varscan2
- USP7 | c.542_543del p.K181Rfs*5 | Frame Shift Del (DEL) | VAF 9/50 reads (18%) | called by mutect2, pindel, varscan2
- MKI67 | c.5988G>A p.K1996= | Silent (SNP) | VAF 58/120 reads (48%) | called by muse, mutect2, varscan2
- NYNRIN | c.790C>T p.L264= | Silent (SNP) | VAF 28/75 reads (37%) | catalogued as rs756824618; called by muse, mutect2, varscan2
- COL6A3 | c.6591+31G>T | Intron (SNP) | VAF 9/34 reads (26%) | called by muse, mutect2, varscan2
- IGHV3-21 | chr14:106235063 ins CGCGA | 3'Flank (INS) | VAF 6/49 reads (12%) | called by mutect2, pindel*, varscan2
- MTTP | c.-65G>A | 5'UTR (SNP) | VAF 19/35 reads (54%) | called by muse, mutect2, varscan2
- STK4 | c.*65T>A | 3'UTR (SNP) | VAF 4/27 reads (15%) | called by muse, mutect2
